Somatic mutation profile of tumor specimen C3N-02675-04 (aliquot CPT0187370006) from CPTAC case C3N-02675, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 69.4 years (25,361 days).
Specimen C3N-02675-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a52bc9fd-752b-4b4e-a2d7-04c55646e6e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02675-31 (Blood Derived Normal), aliquot CPT0187410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd36de11-5788-48b6-b259-a782b2ad645f

The open-access MAF lists 294 somatic variants for this specimen: 180 protein-altering or splice-affecting, 76 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 76, Intron 18, Nonsense Mutation 14, Splice Site 7, Frame Shift Del 5, 3'UTR 5, 5'UTR 5, RNA 4, 5'Flank 4, Splice Region 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 39/262 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV58701142; called by muse, mutect2
- AGFG1 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1233607456; called by muse, mutect2
- AKT1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV62573196; called by muse, mutect2, varscan2
- ANKRD31 | c.3190G>C p.E1064Q | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV57156535; called by muse, mutect2
- CACNB1 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59998429; called by muse, mutect2
- CBFB | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 19/194 reads (10%) | catalogued as COSV52000547; called by muse, mutect2
- CCDC102B | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV99076767; called by muse, varscan2
- CD163 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 260/690 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs1332860579; called by muse, mutect2, varscan2
- CFAP94 | c.542G>T p.G181V (on ENST00000320267 / NM_001352064.2; = p.G187V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs748961237; called by muse, mutect2, varscan2
- COL17A1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.013); catalogued as rs146043118; called by muse, mutect2
- COLEC12 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV68372475; called by muse, mutect2
- CR2 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 10/129 reads (8%) | catalogued as rs766671758, COSV65506850; called by muse, mutect2
- CUX2 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs771025328; called by muse, mutect2, varscan2
- DCC | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV59127401; called by muse, mutect2, varscan2
- DES | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1057520275, COSV64660369; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2I1 | c.3047G>A p.G1016D | Missense Mutation (SNP) | VAF 32/445 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV68103602, COSV68105018; called by muse, mutect2
- ERN2 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV56837573, COSV99892291; called by muse, mutect2
- FAM111B | c.312C>G p.S104R | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59112197; called by muse, mutect2, varscan2
- FANCI | c.2660C>T p.S887L (on ENST00000310775 / NM_001376911.1; = p.S827L on NM_018193.3) | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs767752212; called by muse, mutect2, varscan2
- FERMT1 | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV54093169; called by muse, mutect2, varscan2
- FNDC3A | c.977+1G>T p.X326_splice (on ENST00000492622 / NM_001079673.2; = p.X270_splice on NM_014923.5) | Splice Site (SNP) | VAF 5/79 reads (6%) | catalogued as rs1299786708; called by muse, mutect2
- GATA3 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV60517130; called by muse, mutect2, varscan2
- HMCN1 | c.11056G>A p.D3686N | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54926245; called by muse, varscan2
- ITPRID2 | c.3082G>A p.G1028S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.045); catalogued as rs1439144846; called by muse, mutect2, varscan2
- ITSN1 | c.3289C>T p.P1097S | Missense Mutation (SNP) | VAF 24/351 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs754177477; called by muse, mutect2
- KANK2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764452697, COSV100763392; called by muse, mutect2
- KDM5A | c.1656G>T p.V552= | Splice Region (SNP) | VAF 223/518 reads (43%) | catalogued as rs1342496574; called by muse, mutect2, varscan2
- LRRCC1 | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV64482871; called by muse, mutect2
- LRRK2 | c.4179G>T p.W1393C | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54174385; called by muse, mutect2
- LRRTM4 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 60/486 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV69155618; called by muse, mutect2, varscan2
- MED13L | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 36/209 reads (17%) | catalogued as COSV56129484; called by muse, mutect2, varscan2
- MGLL | c.509T>C p.V170A (on ENST00000398104 / NM_001003794.2; = p.V180A on NM_007283.6) | Missense Mutation (SNP) | VAF 56/722 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1211052527; called by muse, mutect2
- MME | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as COSV64706820; called by muse, mutect2
- NCAPG | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1189574918, COSV99265696; called by muse, mutect2
- NOTCH1 | c.5018+1G>T p.X1673_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV53025505; called by muse, mutect2, varscan2
- NPHP3 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs538520481; called by muse, mutect2, varscan2
- NUP160 | c.3320G>T p.R1107L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65855594; called by muse, mutect2, varscan2
- OR2G3 | c.464G>T p.S155I | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs1361424237; called by muse, mutect2
- OR2T1 | c.322G>T p.G108* | Nonsense Mutation (SNP) | VAF 24/188 reads (13%) | catalogued as COSV100822341; called by muse, mutect2, varscan2
- OR2T3 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV62083981; called by muse, mutect2
- OR4M1 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as rs561146697; called by muse, mutect2
- OR5K1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.673); catalogued as rs1378734652; called by muse, mutect2
- OR9Q1 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1302221607; called by muse, mutect2
- OTOP1 | c.1154C>G p.P385R | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56395464; called by muse, mutect2
- PCDH15 | c.4784T>C p.I1595T | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.071); catalogued as rs138788812; called by muse, mutect2, varscan2
- PCDHA1 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100974485; called by muse, mutect2, varscan2
- PGK2 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59163840; called by muse, mutect2, varscan2
- PKD1 | c.4789A>G p.I1597V | Missense Mutation (SNP) | VAF 79/1198 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as rs765114440; called by muse, mutect2
- PLCZ1 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56848471; called by muse, mutect2, varscan2
- PRKACA | c.132T>A p.F44L | Missense Mutation (SNP) | VAF 33/327 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as rs1348252622; called by muse, mutect2, varscan2
- RHOB | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55356584; called by muse, mutect2, varscan2
- RHOU | c.131del p.G44Vfs*24 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs1553255068; called by mutect2, pindel
- SAMM50 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244139143, COSV63110692; called by muse, mutect2
- SCAPER | c.160A>G p.R54G | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.465); catalogued as rs1407015123; called by muse, mutect2, varscan2
- SIGLEC11 | c.1172G>T p.C391F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766335832; called by muse, mutect2
- SLC24A2 | c.559C>G p.P187A | Missense Mutation (SNP) | VAF 163/391 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645982; called by muse, mutect2, varscan2
- SLC45A4 | c.616G>A p.G206S (on ENST00000517878 / NM_001286646.2; = p.G155S on NM_001080431.2) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480702133; called by mutect2, varscan2
- SLC5A3 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747641336; called by muse, mutect2, varscan2
- SLC9A6 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs782109482, COSV100857872; called by muse, mutect2
- SNED1 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100122818; called by muse, mutect2
- SPTBN2 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs551052303, COSV59448650; called by muse, mutect2, varscan2
- TCFL5 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104371784; called by muse, mutect2, varscan2
- TG | c.5309A>T p.E1770V | Missense Mutation (SNP) | VAF 31/396 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV55075358; called by muse, mutect2
- TUBGCP6 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs1331941025; called by muse, mutect2, varscan2
- YIPF6 | c.697T>G p.F233V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.164); catalogued as COSV101006255; called by muse, mutect2, varscan2
- ZBTB38 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs555322688, COSV58542433; called by muse, mutect2
- ZEB2 | c.191G>C p.S64T | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV57952313; called by muse, mutect2, varscan2
- ZFYVE16 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV62016421; called by muse, mutect2
- ACADM | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ACTC1 | c.523del p.H175Mfs*18 | Frame Shift Del (DEL) | VAF 44/344 reads (13%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.4148A>G p.Y1383C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGA | c.1036A>T p.I346F | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.6880A>G p.K2294E | Missense Mutation (SNP) | VAF 57/396 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AL136295.1 | c.2204G>C p.G735A | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ANKFN1 | c.3373C>A p.L1125I (on ENST00000653862; = p.L978I on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/520 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ASCC3 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ATG13 | c.500-1G>A p.X167_splice | Splice Site (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- ATG13 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); called by muse, mutect2
- B4GALT3 | c.180C>G p.H60Q | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1A | c.1287C>A p.S429R | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); called by muse, mutect2
- CACNA1A | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- CDH10 | c.915A>C p.E305D | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2
- CNGA1 | c.1069A>C p.T357P | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A5 | c.4862G>A p.G1621E | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CREB3L1 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CXCR4 | c.16-2A>T p.X6_splice | Splice Site (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- CYP1B1 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYP2C9 | c.169-3T>C | Splice Region (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- DGAT2L6 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DLG2 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- DLK1 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 64/509 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNA2 | c.1012A>T p.T338S | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); called by muse, mutect2
- DOCK6 | c.5038G>C p.E1680Q | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2
- DOCK6 | c.4564G>C p.E1522Q | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- DPP10 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.075); called by muse, mutect2
- DPP9 | c.2035G>T p.G679C (on ENST00000598800; = p.G708C on NM_139159.5) | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- EEFSEC | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 88/937 reads (9%) | called by muse, mutect2
- EPB41L3 | c.1355A>G p.Q452R | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.127); called by muse, mutect2
- ERN2 | c.1237T>A p.S413T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- FIGN | c.581T>G p.L194W | Missense Mutation (SNP) | VAF 22/331 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- FNBP1 | c.1420A>C p.K474Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.325); called by muse, mutect2
- FNDC1 | c.1130T>C p.V377A | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GHR | c.1108C>A p.H370N | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- GOLGA6L22 | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GRIK4 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- GRIK4 | c.1529T>A p.V510E | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- GUCY1B1 | c.1675A>T p.K559* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- GUCY2C | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- HADHB | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOGA1 | c.431_449del p.R144Pfs*46 | Frame Shift Del (DEL) | VAF 28/258 reads (11%) | called by mutect2, pindel
- HSPG2 | c.10456C>T p.L3486= | Splice Region (SNP) | VAF 28/202 reads (14%) | called by muse, mutect2, varscan2
- IFT140 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- IRX2 | c.906del p.A303Rfs*96 | Frame Shift Del (DEL) | VAF 40/347 reads (12%) | called by mutect2, pindel, varscan2
- JAG1 | c.2912C>G p.S971* | Nonsense Mutation (SNP) | VAF 34/314 reads (11%) | called by muse, mutect2, varscan2
- KCNJ3 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LEPR | c.884T>A p.V295E | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2
- LINGO4 | c.49_55del p.L17Sfs*49 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel
- LRFN1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRRC40 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- LSAMP | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MIA3 | c.5366C>G p.P1789R | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- MMD | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2
- MMP27 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2
- MRGPRX2 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- MVB12A | c.660C>G p.F220L | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- NBPF12 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 31/633 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.372); called by muse, mutect2
- NEUROD6 | c.310A>T p.R104W | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2T5 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2
- OR4K5 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 36/554 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2
- OR5B3 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- P3H2 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2
- PCDH11X | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA1 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PCDHA8 | c.2297A>G p.K766R | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PCDHGA5 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 58/493 reads (12%) | called by muse, mutect2, varscan2
- PCNT | c.5994+1G>T p.X1998_splice | Splice Site (SNP) | VAF 23/516 reads (4%) | called by muse, mutect2
- PDE10A | c.1771A>G p.M591V | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PDE1C | c.349A>C p.M117L | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.079); called by muse, mutect2
- PDHA2 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- PJVK | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PLCB2 | c.2122T>C p.F708L | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- PLXNA4 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.163); called by muse, mutect2
- POLQ | c.50C>G p.S17* | Nonsense Mutation (SNP) | VAF 46/514 reads (9%) | called by muse, mutect2
- POTEC | c.1301C>G p.T434S | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- PPP1R35 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.026); called by muse, mutect2
- PPP1R9A | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- PROKR1 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTEN | c.449dup p.A151Gfs*29 | Frame Shift Ins (INS) | VAF 24/188 reads (13%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.4226G>T p.G1409V | Missense Mutation (SNP) | VAF 45/858 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2
- RPS6KA4 | c.1826T>G p.F609C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRBP1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 53/534 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); called by muse, varscan2
- RUVBL1 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RXFP4 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); called by muse, varscan2
- SACS | c.2752A>G p.K918E | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC25A39 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SMPD1 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- SNTG1 | c.1273G>C p.A425P | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- SOCS6 | c.359G>C p.R120T | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SORL1 | c.4888C>T p.Q1630* | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- SPOPL | c.1082A>T p.Q361L | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- ST6GAL2 | c.1042-1G>T p.X348_splice | Splice Site (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- STX8 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TBX22 | c.357-1G>T p.X119_splice | Splice Site (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- TDP2 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, varscan2
- TF | c.1635G>C p.E545D | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); called by muse, mutect2
- TFR2 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TIPARP | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TMEM203 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | called by muse, varscan2
- TNR | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TOPBP1 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TPR | c.6332G>T p.R2111L | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTN | c.93458G>A p.G31153E (on ENST00000591111; = p.G23729E on NM_003319.4) | Missense Mutation (SNP) | VAF 16/213 reads (8%) | PolyPhen probably damaging (1); called by muse, mutect2
- WDR24 | c.1343C>G p.S448C (on ENST00000248142; = p.S318C on NM_032259.4) | Missense Mutation (SNP) | VAF 52/399 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WSCD2 | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 84/453 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- ZIM3 | c.1224C>G p.S408R | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.18); called by muse, mutect2
- ZNF527 | c.1384A>T p.R462* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- ZNF682 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF727 | c.338T>C p.L113S | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF98 | c.139A>T p.R47* | Nonsense Mutation (SNP) | VAF 16/179 reads (9%) | called by muse, mutect2
- ANPEP | c.2862C>T p.N954= | Silent (SNP) | VAF 33/263 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.207G>A p.R69= | Silent (SNP) | VAF 62/638 reads (10%) | called by muse, mutect2
- ARMC3 | c.2106A>T p.V702= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as COSV53058960; called by muse, mutect2, varscan2
- ATP7B | c.3462G>A p.L1154= | Silent (SNP) | VAF 19/282 reads (7%) | catalogued as rs767069278, COSV99666557; called by muse, mutect2
- AUTS2 | c.3615C>T p.N1205= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs567354186; called by muse, mutect2, varscan2
- BICD2 | c.1350C>T p.R450= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as rs368443099; called by muse, mutect2, varscan2
- CCDC88B | c.1617A>T p.S539= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- CLASRP | c.1335G>C p.G445= | Silent (SNP) | VAF 39/390 reads (10%) | called by muse, mutect2, varscan2
- CRB1 | c.2922C>G p.T974= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs746616083; called by muse, mutect2, varscan2
- CSMD3 | c.1575C>A p.T525= (on ENST00000297405 / NM_001363185.1; = p.T421= on NM_052900.3) | Silent (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- DOCK4 | c.3198G>C p.L1066= | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- EPRS1 | c.3210A>G p.K1070= | Silent (SNP) | VAF 35/202 reads (17%) | catalogued as rs1270441407, COSV100859541; called by muse, mutect2, varscan2
- ERICH3 | c.3975C>T p.N1325= | Silent (SNP) | VAF 35/396 reads (9%) | catalogued as rs1209806791, COSV100443656; called by muse, mutect2
- FGD6 | c.4011T>C p.S1337= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs1160423328; called by muse, mutect2, varscan2
- FKBPL | c.126T>A p.P42= | Silent (SNP) | VAF 65/333 reads (20%) | called by muse, mutect2, varscan2
- FNBP1 | c.1419G>A p.Q473= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- FOXI1 | c.495C>G p.A165= | Silent (SNP) | VAF 84/821 reads (10%) | catalogued as rs764273040, COSV100089473; called by muse, mutect2, varscan2
- FOXK1 | c.2067C>T p.T689= | Silent (SNP) | VAF 75/602 reads (12%) | catalogued as rs538698881; called by muse, mutect2, varscan2
- GHR | c.1842G>A p.L614= | Silent (SNP) | VAF 34/320 reads (11%) | called by muse, mutect2, varscan2
- GPR37L1 | c.150T>C p.D50= | Silent (SNP) | VAF 45/321 reads (14%) | called by muse, mutect2, varscan2
- GPR42 | c.345G>C p.L115= | Silent (SNP) | VAF 37/608 reads (6%) | catalogued as rs773190469; called by muse, mutect2
- GTF3C2 | c.2502G>A p.L834= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV51990273; called by muse, mutect2
- HS3ST1 | c.318G>A p.Q106= | Silent (SNP) | VAF 38/378 reads (10%) | called by muse, mutect2, varscan2
- IGLV2-18 | c.282G>A p.L94= | Silent (SNP) | VAF 40/501 reads (8%) | called by muse, mutect2
- IGSF22 | c.1959C>G p.R653= | Silent (SNP) | VAF 37/459 reads (8%) | catalogued as COSV60035499, COSV60037187; called by muse, mutect2
- IL7R | c.282C>A p.I94= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as rs778067695, COSV57408483; called by muse, mutect2, varscan2
- ITFG1 | c.1161G>A p.L387= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV57750230; called by muse, mutect2, varscan2
- KCNC2 | c.582C>T p.D194= | Silent (SNP) | VAF 58/301 reads (19%) | catalogued as rs768447661, COSV54363256; called by muse, mutect2, varscan2
- KIR3DL2 | c.1032G>T p.G344= | Silent (SNP) | VAF 32/228 reads (14%) | catalogued as COSV54393717; called by muse, mutect2, varscan2
- LAMA2 | c.7131G>A p.L2377= | Silent (SNP) | VAF 50/248 reads (20%) | catalogued as rs1389553440, COSV70341099; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRATD2 | c.744G>A p.E248= | Silent (SNP) | VAF 20/332 reads (6%) | called by muse, mutect2
- LTN1 | c.315T>C p.Y105= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- MAMDC4 | c.1227G>C p.G409= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV99915587; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1354C>A p.R452= (on ENST00000551404 / NM_139078.3; = p.R450= on NM_003668.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- MCTS1 | c.486T>C p.I162= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1225732950; called by muse, mutect2, varscan2
- MIS18BP1 | c.2253G>A p.L751= | Silent (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- NAT1 | c.210G>A p.Q70= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV56984560; called by muse, mutect2
- NCAPD2 | c.2169G>C p.L723= | Silent (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- NEXMIF | c.2760A>G p.Q920= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs776150276; called by muse, mutect2, varscan2
- NEXMIF | c.1797G>A p.T599= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs144467442; called by muse, mutect2, varscan2
- NLGN1 | c.132A>G p.L44= | Silent (SNP) | VAF 92/385 reads (24%) | catalogued as rs1271250368; called by muse, mutect2, varscan2
- NPAS3 | c.1233T>C p.S411= (on ENST00000356141 / NM_001164749.2; = p.S379= on NM_022123.3) | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as rs111643042; called by muse, mutect2
- NRXN2 | c.4719C>A p.P1573= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- NUBP1 | c.750G>A p.G250= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as rs914688100; called by muse, mutect2, varscan2
- OR2AG1 | c.144T>A p.A48= | Silent (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- OR5A1 | c.78C>G p.L26= | Silent (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2
- PCDH15 | c.166C>T p.L56= | Silent (SNP) | VAF 15/190 reads (8%) | catalogued as COSV57398973; called by muse, mutect2
- PCDHGC4 | c.1659A>G p.L553= | Silent (SNP) | VAF 30/456 reads (7%) | called by muse, mutect2
- PDE2A | c.933C>A p.L311= | Silent (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- PODNL1 | c.9G>C p.P3= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs573862960; called by muse, mutect2, varscan2
- PROM2 | c.2058C>T p.S686= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as rs372185353; called by muse, mutect2
- PRR12 | c.3030G>A p.E1010= (on ENST00000615927; = p.E1831= on NM_020719.3) | Silent (SNP) | VAF 7/51 reads (14%) | called by mutect2, varscan2
- PSEN2 | c.1290G>C p.T430= | Silent (SNP) | VAF 56/434 reads (13%) | catalogued as rs1489614058; called by muse, mutect2, varscan2
- PTPRH | c.1197C>T p.N399= | Silent (SNP) | VAF 24/257 reads (9%) | called by muse, mutect2
- R3HDM2 | c.183T>C p.H61= | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as rs1301154233; called by muse, mutect2, varscan2
- RARG | c.609G>C p.S203= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- RYR3 | c.3120T>G p.A1040= | Silent (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- SATB2 | c.2001G>A p.R667= | Silent (SNP) | VAF 41/576 reads (7%) | called by muse, mutect2
- SCART1 | c.2208C>T p.A736= | Silent (SNP) | VAF 46/469 reads (10%) | catalogued as rs1294717524; called by muse, mutect2
- SCNN1A | c.612T>C p.R204= | Silent (SNP) | VAF 35/338 reads (10%) | catalogued as rs1430035555; called by muse, mutect2, varscan2
- SERPINA7 | c.420G>A p.L140= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV59664839; called by muse, mutect2, varscan2
- SIM1 | c.1932T>C p.H644= | Silent (SNP) | VAF 43/246 reads (17%) | called by muse, mutect2, varscan2
- SMG5 | c.795A>G p.Q265= | Silent (SNP) | VAF 29/213 reads (14%) | catalogued as rs1382917801; called by muse, mutect2, varscan2
- STON2 | c.2163C>T p.F721= (on ENST00000649389 / NM_001366849.2; = p.F664= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/200 reads (17%) | catalogued as COSV50843702, COSV50845658; called by muse, mutect2, varscan2
- TACC3 | c.1602G>A p.T534= | Silent (SNP) | VAF 17/246 reads (7%) | catalogued as rs1421884078, COSV57606768; called by muse, mutect2
- TAS2R14 | c.840G>A p.L280= | Silent (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- TCFL5 | c.252G>T p.A84= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- THEG | c.615G>A p.L205= | Silent (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- THOP1 | c.837C>A p.V279= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- TMEM132C | c.1737G>A p.V579= | Silent (SNP) | VAF 47/313 reads (15%) | called by muse, mutect2, varscan2
- TMEM144 | c.120C>G p.L40= | Silent (SNP) | VAF 12/105 reads (11%) | called by muse, mutect2, varscan2
- TMEM225 | c.672T>G p.A224= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- TRGV4 | c.99T>A p.T33= | Silent (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- UNC80 | c.7212T>C p.L2404= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- ZNF317 | c.1701C>T p.F567= | Silent (SNP) | VAF 24/253 reads (9%) | called by muse, mutect2
- ZNF610 | c.804G>A p.V268= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- AC073254.1 | chr2:232581038 G>A | 3'Flank (SNP) | VAF 60/469 reads (13%) | called by muse, mutect2, varscan2
- ACSF3 | c.-116C>T | 5'UTR (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.616+24327G>A | Intron (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- APLN | c.*209A>G | 3'UTR (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- ARHGDIA | c.*128G>A | 3'UTR (SNP) | VAF 25/147 reads (17%) | catalogued as rs756985934; called by muse, mutect2, varscan2
- ATP13A2 | c.348-27G>A | Intron (SNP) | VAF 38/426 reads (9%) | catalogued as rs1011484580; called by muse, mutect2
- BPNT2 | c.647-862A>T | Intron (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- CC2D1B | c.2448+226del | Intron (DEL) | VAF 21/164 reads (13%) | called by mutect2, pindel, varscan2
- CD96 | c.*33G>C | 3'UTR (SNP) | VAF 52/228 reads (23%) | called by muse, mutect2, varscan2
- F13A1 | c.1113-9152A>T | Intron (SNP) | VAF 24/121 reads (20%) | catalogued as COSV99343178; called by muse, mutect2, varscan2
- GPATCH4 | chr1:156595074 C>A | 3'Flank (SNP) | VAF 21/175 reads (12%) | catalogued as COSV100576926; called by muse, mutect2, varscan2
- GPR162 | c.867+11G>T | Intron (SNP) | VAF 42/419 reads (10%) | catalogued as COSV50593903; called by muse, mutect2
- H3P12 | chr3:109410139 C>A | 5'Flank (SNP) | VAF 64/327 reads (20%) | called by muse, mutect2, varscan2
- KIAA1328 | c.-6T>A | 5'UTR (SNP) | VAF 19/303 reads (6%) | called by muse, mutect2
- LGR6 | c.1137-86A>G | Intron (SNP) | VAF 29/144 reads (20%) | catalogued as rs1404826425; called by muse, mutect2, varscan2
- LINC00293 | n.521C>A | RNA (SNP) | VAF 19/214 reads (9%) | called by muse, mutect2
- LRR1 | chr14:49598556 G>A | 5'Flank (SNP) | VAF 44/448 reads (10%) | called by muse, mutect2
- LRR1 | chr14:49598557 C>A | 5'Flank (SNP) | VAF 44/434 reads (10%) | called by muse, mutect2, varscan2
- MDGA2 | c.1525+1880G>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- NIBAN3 | c.1844-1494C>T | Intron (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2
- NUB1 | c.417-635C>A | Intron (SNP) | VAF 18/205 reads (9%) | called by muse, mutect2
- OR10AB1P | n.153T>C | RNA (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- OR2L1P | n.749C>G | RNA (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2, varscan2
- PDX1 | c.-24G>A | 5'UTR (SNP) | VAF 46/624 reads (7%) | catalogued as rs779510037; called by muse, mutect2
- PLA2G1B | c.-17C>G | 5'UTR (SNP) | VAF 36/193 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1845+3185G>T | Intron (SNP) | VAF 29/129 reads (22%) | catalogued as COSV100163734; called by muse, mutect2, varscan2
- RBM5 | c.1768-30G>A | Intron (SNP) | VAF 33/257 reads (13%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891028 C>G | 5'Flank (SNP) | VAF 15/189 reads (8%) | called by muse, mutect2
- SATB2 | c.*33G>T | 3'UTR (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- SATB2 | c.347-15936C>A | Intron (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- SHMT1 | c.243-90C>T | Intron (SNP) | VAF 54/469 reads (12%) | called by muse, mutect2, varscan2
- TEKT3 | c.735-40A>C | Intron (SNP) | VAF 42/310 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2111C>A | Intron (SNP) | VAF 34/249 reads (14%) | catalogued as COSV62467652; called by muse, mutect2, varscan2
- TNFSF11 | c.-3G>T | 5'UTR (SNP) | VAF 50/698 reads (7%) | called by muse, mutect2
- TPM4 | c.*118G>A | 3'UTR (SNP) | VAF 45/461 reads (10%) | catalogued as rs1180864355, COSV56289884; called by muse, mutect2
- TTN | c.10360+2384T>A | Intron (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- ZNF490 | c.162+11993C>T | Intron (SNP) | VAF 40/419 reads (10%) | called by muse, mutect2
- ZNF849P | n.1303A>G | RNA (SNP) | VAF 19/200 reads (10%) | catalogued as rs1444904100; called by muse, mutect2
